Gene-level copy-number profile of tumor specimen TCGA-05-5715-01A from TCGA case TCGA-05-5715, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.5 years (25,383 days).
Specimen TCGA-05-5715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.fd212b09-f511-4394-a59d-9921ecc8b686.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-5715-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21934331-9310-441f-9449-fa05f931b34b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 12,507; copy number 2: 42,421; copy number 3: 3,218; copy number 4: 1,085; copy number 5: 470; copy number 6: 96.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-5715-01A-01D-1624-01): tumor purity 0.73, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,029,594, 10 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:25,647,570–25,819,426, 5 genes: GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 566 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:165,827,614–167,166,479, 31 genes, copy number 5 (within-gene range 3–5): UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1, AL596087.3, MIR921, AL596087.2, AL596087.1, AL583804.1, FMO7P, LINC01675, FMO8P, FMO9P, FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1.
- chr1:170,271,395–174,996,629, 96 genes, copy number 5 (broad region; genes not listed).
- chr1:184,387,029–184,629,019, 1 gene, copy number 5 (within-gene range 3–5): C1orf21.
- chr1:184,566,511–201,509,456, 208 genes, copy number 5–6 (broad region; genes not listed).
- chr1:203,626,787–205,896,082, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:214,870,734–224,035,056, 130 genes, copy number 5–6 (broad region; genes not listed).
- chr1:238,476,542–239,052,903, 6 genes, copy number 5: LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1.
- chr5:4,451,930–4,970,425, 7 genes, copy number 5 (within-gene range 3–5): AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3.
- chr14:36,320,753–36,656,163, 1 gene, copy number 5 (within-gene range 3–5): AL132857.1.
- chr14:36,473,207–36,679,362, 10 genes, copy number 5: SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9.

Autosomal genes at a single copy (total copy number 1): 12,507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
